MMRF case MMRF_1930 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0578011e-b7d6-40b2-996b-99ac29999d08

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 57 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 57.6 years (21,040 days); ISS stage: I; Days to last known disease status: 1,065 days (2.9 years); Days to last follow up: 1,065 days (2.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 59 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 87 days; Days to treatment end: 87 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 113 days; Days to treatment end: 113 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 115 days; Days to treatment end: 115 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 224 days; Days to treatment end: 256 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 224 days; Days to treatment end: 273 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 224 days; Days to treatment end: 259 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 274 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -18 (ECOG 0): M Protein 0.74 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.451 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 70 mg/dL; Immunoglobulin G 7.98 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 2.38 µg/mL; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 9.05 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.4 mmol/L; Albumin 45 g/L; Total Protein 7.2 g/dL; Glucose 5.56 mmol/L; C-Reactive Protein 0.5 mg/dL.
- Day 59 (ECOG 0): M Protein 0.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.809 mg/dL; Immunoglobulin G 3.52 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 2.02 µg/mL; Lactate Dehydrogenase 0.433 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 6.5 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 5.67 mmol/L.
- Day 143 (ECOG 0): M Protein 0.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.743 mg/dL; Immunoglobulin G 3.18 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 0.28 µg/mL; Lactate Dehydrogenase 3.15 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.38 mmol/L; Albumin 44 g/L; Total Protein 6 g/dL; Glucose 5.78 mmol/L.
- Day 246 (ECOG 0): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Immunoglobulin G 5.7 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.55 g/L; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 47 g/L; Total Protein 6.9 g/dL; Glucose 8.14 mmol/L.
- Day 330 (ECOG 0): M Protein 0.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.67 mg/dL; Immunoglobulin G 6.19 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.08 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 5.45 mmol/L.
- Day 442 (ECOG 0): M Protein 0.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.42 mg/dL; Immunoglobulin G 8.51 g/L; Immunoglobulin A 0.96 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.02 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 5.17 mmol/L.
- Day 526 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.64 mg/dL; Immunoglobulin G 9.1 g/L; Immunoglobulin A 1.09 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 1.9 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 2.95 ×10⁹/L; Absolute Neutrophil 1.27 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 5.23 mmol/L.
- Day 610 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.75 mg/dL; Immunoglobulin G 9.3 g/L; Immunoglobulin A 1.24 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.02 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 3.16 ×10⁹/L; Absolute Neutrophil 1.38 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 5.12 mmol/L.
- Day 694 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.64 mg/dL; Immunoglobulin G 9.37 g/L; Immunoglobulin A 1.18 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 1.98 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 2.87 ×10⁹/L; Absolute Neutrophil 1.25 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 5.28 mmol/L.
- Day 806 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.83 mg/dL; Immunoglobulin G 9.83 g/L; Immunoglobulin A 1.41 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.02 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.53 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.38 mmol/L; Albumin 45 g/L; Total Protein 7 g/dL; Glucose 5.5 mmol/L.
- Day 871 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.53 mg/dL; Immunoglobulin G 9.9 g/L; Immunoglobulin A 1.4 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 3.51 ×10⁹/L; Absolute Neutrophil 1.87 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL; Glucose 5.72 mmol/L.
- Day 981 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.89 mg/dL; Immunoglobulin G 9.99 g/L; Immunoglobulin A 1.58 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 1.9 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 3.25 ×10⁹/L; Absolute Neutrophil 1.43 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 5.45 mmol/L.
- Day 1,065 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.16 mg/dL; Immunoglobulin G 9.98 g/L; Immunoglobulin A 1.53 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 1.95 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 3.14 ×10⁹/L; Absolute Neutrophil 1.37 ×10⁹/L; Platelets 131 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 5.45 mmol/L.

Other clinical attributes
- Day -18: Weight: 86 kg; Height: 175 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1930_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -18 days.
- Sample MMRF_1930_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -18 days.
